Surgical pathology report (de-identified scan), TCGA case TCGA-14-0781, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-0781-01B (Primary Tumor).

[page 1 of 4]
AP Report

* Final Report *

TCGA-14-0781

Document Type: AP Report
Document Date:
Document Status: Auth (Verified)
Document Title: Anatomic Pathology Report
Encounter info:

* Final Report *

Anatomic Pathology Report

Patient:

Accession Number:

Patient Number:

Date Collected:

Financial Number:

Date Received:

Room/Bed:

PT:

Admitting Physician:

Ordering Physician:

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. LEFT PARIETAL BRAIN LESION, RESECTION, FS1A, TP1A:
- GLIOBLASTOMA (WHO GRADE IV).
2. LEFT PARIETAL BRAIN LESION, RESECTION:
- GLIOBLASTOMA (WHO GRADE IV).

SPECIMEN:

1. Left parietal brain lesion,
2. Left parietal brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

NAME OF OPERATIVE DIAGNOSIS: Left craniotomy.

PREOPERATIVE DIAGNOSIS: Brain tumor.

POSTOPERATIVE DIAGNOSIS: Brain tumor.

[page 2 of 4]
AP Report

* Final Report *

CGA-14-0781

GROSS DESCRIPTION:

Received are two specimens.

Specimen #1 is received fresh for intraoperative consultation and is labeled "left parietal brain lesion". The specimen consists of multiple fragments of soft, hemorrhagic brain tissue measuring in aggregate 1 x 1 x 0.3 cm. Representative sections of the specimen are submitted for frozen section evaluation and the remainder of the cryoblock is submitted in cassette "FS1A". The remainder of the specimen is entirely submitted in cassette "1B".

Specimen #2 is received in formalin, labeled with the patient's name, hospital number and is unlabeled but the accompanying requisition form is labeled "left parietal brain lesion". The specimen consists of multiple fragments of gray-tan tissue measuring 2.6 x 2.3 x 0.5 cm. The specimen is submitted entirely in cassettes "2A" and "2B".

INTRAOPERATIVE CONSULTATION:

FS1A: LEFT PARIETAL BRAIN LESION (FROZEN SECTION AND TOUCH PREPARATIONS):
GLIOBLASTOMA.

Pathologist:

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

TISSUE COMMITTEE CODE:

1

Resident: _

Fellow: _

The pathologist has reviewed and interpreted the case with the resident/fellow.

[page 3 of 4]
AP Report

* Final Report *

TCGA-14-0781

Patient:

Accession Number:

Patient Number:

SURGICAL PATHOLOGY REPORT

ICD-9 CODES:
191.3

[page 4 of 4]
[REDACTED]

AP Report

* Final Report *

[REDACTED]

TCGA-14-0781

Medical Records

Page 2 (End of Report)

[REDACTED]

[REDACTED]

Page 4 of 4
(End of Report)

Source: NCI Genomic Data Commons file fbe54bab-a0e4-49f3-8d5c-b474eb0b7f67 (TCGA-14-0781.0CA697B0-9C0E-45A7-AAC1-72480CFCCD9B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).